Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51E, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51E-06A (Metastatic).

[page 1 of 2]
***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) LEFT INGUINAL SENTINEL LYMPH NODE #1, BLUE, COUNT 1800:
One lymph node, addendum report to follow.
- (B) LEFT INGUINAL SENTINEL LYMPH NODE #2, NOT BLUE, COUNT 600:
One lymph node, addendum report to follow.
- (C) LEFT INGUINAL SENTINEL LYMPH NODE #3, NOT BLUE, COUNT 390:
One lymph node, addendum report to follow.
- (D) WIDE LOCAL EXCISION, LEFT POSTERIOR LOWER LEG:
METASTATIC MALIGNANT MELANOMA IN DERMIS AND SUBCUTANEOUS TISSUE.
TUMOR SIZE: 40 X 40 X 35 MM.
Peripheral margins are free. Please see specimen E below for deep margin.
- (E) ADDITIONAL DEEP MARGIN:
Fibroadiopose tissue and skeletal muscle, no tumor identified.
- (F) LEFT POPLITEAL SENTINEL LYMPH NODE #1, 480, NOT BLUE:
One lymph node, addendum report to follow.

Entire report and diagnosis completed by

ICD-0-3

Melanoma, NOS 8720/3
Site: subcutaneous tissue, leg c49.2
fw
11/6/12

GROSS DESCRIPTION

- (A) LEFT INGUINAL SENTINEL LYMPH NODE #1, BLUE, COUNT 1,800 - One blue lymph node is identified measuring 1.5 x 1.2 x 1.0 cm. Serially sectioned, entirely submitted in A.
- (B) LEFT INGUINAL SENTINEL LYMPH NODE #2, NOT BLUE, COUNT 600 - One lymph node is identified measuring 0.8 x 0.4 x 0.4 cm, bisected entirely submitted in B.
- (C) LEFT INGUINAL SENTINEL LYMPH NODE #3, NOT BLUE, COUNT 390 - One lymph node is identified measuring 0.5 x 0.3 x 0.3 cm. Entirely submitted in C.
- (D) WIDE LOCAL EXCISION, METASTATIC MELANOMA, LEFT POSTERIOR LOWER LEG - An 8.0 x 5.0 x 2.5 cm ellipse of skin with a 4.0 x 4.0 x 3.5 cm tan-pink subcutaneous nodule. The nodule is at least 2.0 cm from all the peripheral margins. It is very close to the deep resection margin. Portions of the tumor were submitted for the vaccine protocol. Additional portions of tumor and non-neoplastic skin were submitted to the Tumor Bank.

INK CODE: Black-resection margin.

SECTION CODE: D1, D2, representative sections of nodule with deep margin; D3, D4, nodule and peripheral margin.

- (E) ADDITIONAL DEEP MARGIN - An unoriented 3.0 x 1.9 x 0.8 cm red skeletal muscle fragment that has a stitch indicating the true margin which has been inked blue. The specimen is serially sectioned and submitted entirely in E1-E3.
- (F) LEFT POPLITEAL SENTINEL LYMPH NODE #1, 480, NOT BLUE - A 1.6 x 1.1 x 1.0 cm yellow-tan lymph node is serially sectioned and submitted in F1 and F2.

CLINICAL HISTORY

Melanoma, left lower leg.

SNOMED CODES

T-02830, M-87203

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."
Released by:

These tests have not been

Start of ADDENDUM

[page 2 of 2]
ADDENDUM

Addendum completed by

COMMENT

(A, B, C, F) Examination of additional tissue levels and an immunohistochemical study on paraffin sections with a anti-melanocytic cocktail (HMB45 and anti-MART1) fails to reveal metastatic melanoma. A single cell labeled with a the cocktail is negative in the HMB45 slide.

SNOMED CODES

T-C4000, M-01100

Released by:

-----END OF REPORT-----

IHPAA Discrepancy		☒

Source: NCI Genomic Data Commons file b86565c5-36d6-4089-80a4-ec9d9ca02bbc (TCGA-D3-A51E.C05E459C-5273-47B4-B828-8CAEAF1CB2C4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).